Surgical pathology report (de-identified scan), TCGA case TCGA-24-1845, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1845-01A (Primary Tumor).

[page 1 of 4]
TCGA-24-1845

SURGICAL PATHOLOGY REPORT
FINAL

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN:

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY (INCLUDING FS1)

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- OVARIAN SURFACE INVOLVEMENT PRESENT
- SEE SYNOPSIS

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY (INCLUDING FS2)

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- OVARIAN SURFACE INVOLVEMENT PRESENT

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- NO EVIDENCE OF MALIGNANCY

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- FOCAL SEROSAL INVOLVEMENT BY POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, "RECTAL TUMOR," EXCISION

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

UTERUS, SEROSAL SURFACE, RADICAL HYSTERECTOMY

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

UTERUS, CERVIX, RADICAL HYSTERECTOMY

- POLYPOID ENDOCERVICITIS

UTERUS, MYOMETRIUM, RADICAL HYSTERECTOMY

- LEIOMYOMA

UTERUS, ENDOMETRIUM, RADICAL HYSTERECTOMY

- SECRETORY PHASE ENDOMETRIUM

SOFT TISSUE, PARAMETRIAL, RADICAL HYSTERECTOMY

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, OMENTUM, EXCISION

- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SKELETAL MUSCLE, DIAPHRAGM, "TUMOR," EXCISION

[page 2 of 4]
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

LYMPH NODE, RIGHT PERIAORTIC, EXCISION

- ONE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY
- SOFT TISSUE DEPOSIT OF POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA (SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

"Brought to frozen section 'right tube and ovary,' consisting of a lobulated mass with a smooth surface, measuring 10.5 x 9.5 x 3 cm, with attached fallopian tube measuring 5 cm in length x 0.7 cm in diameter. The specimen weighs 233 grams. Sectioned to show cystic and solid cut surfaces. A section of the solid area frozen as FS1. Tissue taken for Rest for permanents."

"Also brought to frozen section 'left tube and ovary,' consisting of a lobulated mass measuring 9 x 8.5 x 4 cm, with attached fallopian tube measuring 5.5 cm in length x 1 cm in diameter. Specimen weighs 150 grams. The surface is smooth except for a 0.1 x 0.1 x 0.1 cm firm nodule, which is inked blue. Sections show cystic and solid areas. Solid area and surface nodule frozen as FS2. Tissue taken for Rest for permanents," by

FS1: Right ovary, excision

- "Adenocarcinoma, favor Mullerian," by

FS2: Left ovary, excision

- "Adenocarcinoma, favor Mullerian, with surface involvement,"

Microscopic Description and Comment:

The specimen received labeled "right periaortic lymph node" shows one definitive lymph node with no evidence of malignancy and a soft tissue fragment that is diffusely involved by metastatic poorly differentiated serous adenocarcinoma. Per discussion with we are interpreting this soft tissue tumor fragment as a lymph node that has been effaced by metastatic disease. The patient is staged accordingly in the synoptic report.

History:

The patient is a with a complex pelvic mass and elevated CA125. Operative procedure: Examination under anesthesia, exploratory laparotomy, radical hysterectomy, bilateral salpingo-oophorectomy, omentectomy, and staging biopsies.

Specimen(s) Received:

- A: OVARY AND TUBE, RIGHT
- B: OVARY AND TUBE, LEFT
- C: RECTAL TUMOR
- D: RADICAL HYSTERECTOMY
- E: DIAPHRAGM TUMOR

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

F: OMENTUM
G: LYMPH NODES, RIGHT PERIOARTIC

Gross Description:

The specimens are received in seven formalin-filled containers, each labeled [REDACTED]. The first is labeled "right tube and ovary, FS1/X." It contains a white cassette labeled "FS1," that holds multiple pieces of yellow-tan soft tissue aggregating to 3 x 2 x 0.3 cm. Labeled A1 (FS1). Also in the container is a cystic and solid ovary, previously sectioned, with attached fallopian tube, with the measurements and characteristics described in the intraoperative non-microscopic consultation. The serosal surface is light tan and purple, wrinkled but shiny, with a 2.5 x 2 cm brown-tan surface nodule adjacent to the fallopian tube suspicious for surface tumor involvement. The inferior of the tumor is yellow-tan, hemorrhagic, and spongy, with solid areas measuring up to 5 cm in maximal dimension. The fallopian tube has a purple-tan, smooth exterior, and is sectioned to show a pinpoint lumen. Labeled A2 to A4 - tumor in relation to smooth serosa; A5 to A8 - tumor and capsule in relation to putative surface tumor; A9 to A11 - inferior of solid tumor; A12 - fallopian tube. [REDACTED]

The second container is labeled "left tube and ovary, FS2/X." It contains a white cassette labeled "FS2," that holds multiple pieces of tan soft tissue, two of which have been previously inked blue, aggregating to 2 x 1.4 x 0.3 cm. Labeled B1 (FS2). Also in the container is a cystic ovary with attached fallopian tube, previously opened, with the measurements and characteristics described in the intraoperative non-microscopic consultation. After formalin fixation, the interior of the tumor is tan and fleshy, with solid areas measuring up to 5.5 cm in maximal dimension. The fallopian tube has a purple-tan, smooth, shiny serosa, and is sectioned to show a pinpoint lumen. Labeled B2 to B9 - tumor in relation to serosa; B10 - fallopian tube. [REDACTED]

The third container is labeled "rectal tumor." It contains a 3 x 1.8 x 0.9 cm piece of heterogeneous white-tan and brown soft tissue. It is bisected to show a solid cut surface, similar in appearance to the previously described ovarian tumors. Labeled C1. [REDACTED]

The fourth container is labeled "radical hysterectomy." It contains a uterus and cervix measuring 9 x 5.5 x 4 cm, with attached 4.5 x 3.5 x 0.7 cm right posterior parametrium. The uterine serosa is tan-brown, smooth, and shiny, with a 0.8 cm subserosal nodule near the left anterior fundus. The 4 x 3 cm white-tan ectocervix has an unremarkable transformation zone and is without lesions. The cervical resection margin and parametrial soft tissue are inked blue, and the uterus is bivalved to show a 4.5 x 1.7 cm unremarkable endometrial cavity and endometrial lining, a 2.3 x 1.1 cm unremarkable endocervical canal and endocervical mucosa, and a 1.5 cm in thickness firm tan myometrium. The subserosal nodule is sectioned to show a putative leiomyoma. No other lesions are identified. Labeled D1 - anterior cervix; D2 - posterior cervix; D3 - anterior endomyometrium and subserosal leiomyoma; D4 - posterior endometrium; D5 to D7 - parametrial soft tissue, completely submitted from superior to inferior. [REDACTED]

The fifth container is labeled "diaphragm tumor." It contains a 0.8 x 0.6 x 0.3 cm piece of white-tan soft tissue. Labeled E1. [REDACTED]

The sixth container is labeled "omentum." It contains a 24 x 10 x 2 cm piece of brown-yellow fibroadipose omentum. The serosal surface is smooth and shiny, with omental thickening consistent with diffuse involvement by metastatic disease. These thickened areas are highlighted on cut surface. Labeled F1 to F5. [REDACTED]

The seventh container is labeled "right periaortic lymph nodes." It contains two pieces of yellow-tan fibroadipose tissue aggregating to 2.4 x 1.5 x 0.7 cm. They are dissected to show two putative lymph nodes measuring 0.9 and 1.9 cm. Labeled G1. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS**HISTOPATHOLOGIC TYPE**

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the extrapelvic peritoneum is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is macroscopic but less than 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis 2 cm or less in greatest dimension (T3b/IIIB)

REGIONAL LYMPH NODES (N)

The regional lymph nodes are classified as regional lymph node metastasis (N1)

The total number of regional lymph nodes examined is 2

The total number of metastatically-involved lymph nodes is 1

Extranodal extension by tumor metastases is present

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/N1/M0 (Stage IIIC)

T3b/N1/MX (Stage X)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 7d36f71c-6b8a-4e3f-bb77-34f3a96d1a4b (TCGA-24-1845.1FDA446A-E0D2-422A-A023-57EC5BFAE62B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).